Gene-level copy-number profile of tumor specimen TCGA-A2-A0CM-01A from TCGA case TCGA-A2-A0CM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 41.0 years (14,969 days).
Specimen TCGA-A2-A0CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.34e39e63-405b-4eae-a326-163ea06baa81.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0CM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de16a6af-afcb-4c75-95d7-9b3a1f95bb14

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 1,775; copy number 3: 7,253; copy number 4: 20,350; copy number 5: 9,680; copy number 6: 11,241; copy number 7: 5,857; copy number 8: 2,042; copy number 9: 601; copy number 10: 262; copy number 11: 320; copy number 12: 2; copy number 13: 1; copy number 15: 121; copy number 18: 245; copy number 19: 24; copy number 37: 9; copy number 49: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0CM-01A-31D-A036-01): tumor purity 0.38, ploidy 4.88, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:56,727,418–57,170,306, 6 genes (within-gene range 0–4): ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,607 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,094,987–31,364,953, 7 genes, copy number 10 (within-gene range 6–10): SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1.
- chr1:37,154,761–38,214,806, 46 genes, copy number 11: AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137, ZC3H12A, MIR6732, MEAF6, MIR5581, SNIP1, FTH1P1, AL034379.1, DNALI1, GNL2, AL513220.1, RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, LINC02786, AL390839.1, AL390839.2, LINC01343.
- chr1:143,343,180–162,868,815, 874 genes, copy number 9–19 (within-gene range 7–19) (broad region; genes not listed).
- chr6:41,666,906–41,790,141, 9 genes, copy number 11: NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6.
- chr6:41,791,410–41,791,477, 1 gene, copy number 11: AL365205.3.
- chr6:60,719,222–60,723,898, 2 genes, copy number 12: GAPDHP41, AL590227.1.
- chr6:65,302,522–65,304,957, 1 gene, copy number 13: AL365217.1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 10: AL450336.1, RNU7-66P.
- chr8:110,899,996–111,040,372, 1 gene, copy number 9 (within-gene range 8–9): LINC01608.
- chr8:111,093,263–116,403,757, 26 genes, copy number 9: LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:125,466,939–139,127,953, 152 genes, copy number 9–11 (broad region; genes not listed).
- chr9:22,646,200–25,938,434, 23 genes, copy number 9: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr10:44,712–14,462,142, 250 genes, copy number 10–11 (within-gene range 6–11) (broad region; genes not listed).
- chr11:4,571,423–7,071,526, 171 genes, copy number 9 (broad region; genes not listed).
- chr14:68,421,698–68,628,445, 3 genes, copy number 9: PPIAP6, AL121820.3, AL121820.2.
- chr14:75,202,081–75,427,741, 8 genes, copy number 9: RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2.
- chr19:28,790,812–30,016,612, 31 genes, copy number 37–49: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
